Somatic mutation profile of tumor specimen 0DRZIY from CCDI case PBCHIC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pleomorphic xanthoastrocytoma; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 11.0 years (4,025 days).
Specimen 0DRZIY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a8d6d9f-dc7e-4df6-80b0-3c20cd1e20f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRZJH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13d7e165-ab72-4200-82c8-e977e7675dea

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/532 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by mutect2, varscan2
- NF2 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 32/541 reads (6%) | catalogued as rs1555993345, CM950856, COSV58519797; ClinVar: pathogenic; called by muse, mutect2
- MYH11 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 74/1034 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs886051764; ClinVar: uncertain significance; called by muse, mutect2
- MYO9B | c.4250A>G p.K1417R | Missense Mutation (SNP) | VAF 34/681 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.636); called by muse, mutect2
- NAA38 | c.274T>A p.S92T (on ENST00000575771 / NM_001320925.2; = p.S140T on NM_032356.5) | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.023); called by muse, mutect2
- NXPH2 | c.391A>T p.T131S | Missense Mutation (SNP) | VAF 82/736 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1I | c.1689G>T p.R563= | Silent (SNP) | VAF 65/610 reads (11%) | called by muse, mutect2, varscan2
- PIGR | c.2067C>A p.S689= | Silent (SNP) | VAF 92/1164 reads (8%) | called by muse, mutect2
- MAST4 | c.642+40038G>A | Intron (SNP) | VAF 95/449 reads (21%) | called by muse, mutect2, varscan2
